Somatic mutation profile of tumor specimen TCGA-OR-A5K6-01A (aliquot TCGA-OR-A5K6-01A-11D-A29I-10) from TCGA case TCGA-OR-A5K6, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 56.6 years (20,657 days).
Specimen TCGA-OR-A5K6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be30054c-5ada-481e-88ca-c0faa051bd69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5K6-10A (Blood Derived Normal), aliquot TCGA-OR-A5K6-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6598792b-6f15-437a-8f4c-7547c93da5c7

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, Nonsense Mutation 3, Frame Shift Del 3, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT4 | c.9562G>A p.D3188N | Missense Mutation (SNP) | VAF 9/253 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58698605, COSV58704382; called by muse, mutect2
- H4C2 | c.150G>C p.L50F | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as rs369387838, COSV55138372; called by muse, mutect2
- NBAS | c.1919A>G p.Y640C | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs186337430; called by muse, mutect2, varscan2
- PASK | c.775C>A p.H259N | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs773058115; called by muse, mutect2, varscan2
- PUS1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 100/221 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.101); catalogued as rs1328851064; called by muse, mutect2, varscan2
- SCARB1 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.182); catalogued as rs757101173, COSV99908969; called by muse, varscan2
- SCUBE3 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs765021570, COSV51455982; called by muse, mutect2, varscan2
- SPTBN5 | c.2578C>G p.P860A | Missense Mutation (SNP) | VAF 85/183 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as COSV58023846; called by mutect2, varscan2
- ARHGEF40 | c.1828C>T p.Q610* | Nonsense Mutation (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
- CEACAM20 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 183/434 reads (42%) | called by muse, mutect2, varscan2
- CTNNB1 | c.116_138del p.A39Efs*3 | Frame Shift Del (DEL) | VAF 81/213 reads (38%) | called by mutect2, pindel, varscan2
- ESYT2 | c.1966C>A p.H656N (on ENST00000613624; = p.H580N on NM_020728.3) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2
- IP6K2 | c.905A>G p.E302G | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF13A | c.2624_2657del p.I875Kfs*39 | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | called by mutect2, pindel
- MEN1 | c.1091_1095del p.E364Vfs*6 | Frame Shift Del (DEL) | VAF 68/94 reads (72%) | called by mutect2, pindel, varscan2
- NR5A2 | c.83G>C p.R28P | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ODAM | c.713G>C p.G238A | Missense Mutation (SNP) | VAF 76/196 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- POSTN | c.2058A>C p.E686D | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RHOU | c.746C>A p.S249Y | Missense Mutation (SNP) | VAF 75/178 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- SMC3 | c.1655T>G p.V552G | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ZEB2 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- LYPD1 | c.174G>A p.V58= | Silent (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2
- STRADA | c.549C>T p.L183= (on ENST00000336174 / NM_001363786.1; = p.L146= on NM_153335.6) | Silent (SNP) | VAF 70/278 reads (25%) | catalogued as rs1273514509; called by muse, mutect2, varscan2
- TSPOAP1 | c.1362G>A p.E454= | Silent (SNP) | VAF 19/87 reads (22%) | called by muse, mutect2, varscan2
- DELEC1 | n.562G>T | RNA (SNP) | VAF 16/91 reads (18%) | called by muse, varscan2
